Somatic mutation profile of tumor specimen TCGA-EJ-5498-01A (aliquot TCGA-EJ-5498-01A-01D-1576-08) from TCGA case TCGA-EJ-5498, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.0 years (20,472 days).
Specimen TCGA-EJ-5498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 590a9214-2aa2-4e39-b36c-591c96cbcf4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5498-10A (Blood Derived Normal), aliquot TCGA-EJ-5498-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f25535e-0f76-46d6-9af3-9015589f21c1

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBN | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); catalogued as COSV59828214; called by muse, mutect2, varscan2
- ARHGAP6 | c.1084A>G p.M362V | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as COSV57303876; called by muse, mutect2, varscan2
- BICRAL | c.2244C>A p.D748E | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58408603; called by muse, mutect2, varscan2
- CFH | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66413896; called by muse, mutect2, varscan2
- CYP2A13 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs771991041, COSV100387021, COSV57840255; called by muse, mutect2, varscan2
- EHMT2 | c.3054C>A p.N1018K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57669213; called by muse, mutect2
- FAT4 | c.4525C>T p.R1509W | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs200214434, COSV101272246, COSV67880799; called by muse, mutect2, varscan2
- GNPAT | c.22A>G p.N8D | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs756641192, COSV59643294; called by muse, mutect2, varscan2
- JAM2 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs200218663, COSV57256777; called by muse, mutect2, varscan2
- KYNU | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 71/604 reads (12%) | catalogued as rs779681494, COSV51592078; called by muse, mutect2, varscan2
- LYST | c.10912G>A p.G3638R | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749333802, COSV67714502; called by muse, mutect2, varscan2
- MCF2L | c.1288C>T p.R430C (on ENST00000375608; = p.R398C on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); catalogued as rs557301290, COSV65054114; called by muse, mutect2, varscan2
- MYBPC2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs374389710, COSV63093816; called by muse, mutect2, varscan2
- OBSCN | c.5675C>T p.T1892I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.958); catalogued as COSV52832325; called by muse, mutect2
- PIK3CG | c.2810T>C p.V937A | Missense Mutation (SNP) | VAF 57/382 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63248157; called by muse, mutect2, varscan2
- PON1 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55934010; called by muse, mutect2, varscan2
- RETREG1 | c.1339A>G p.T447A (on ENST00000306320 / NM_001034850.2; = p.T306A on NM_019000.4) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV60452297; called by muse, mutect2, varscan2
- RP1 | c.1064A>T p.K355I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV55127397; called by muse, mutect2, varscan2
- RSBN1 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54735498; called by muse, mutect2, varscan2
- SYNE2 | c.11813G>A p.R3938H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs753878618, COSV59971218; called by muse, mutect2, varscan2
- TAAR9 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1185261467, COSV71512247; called by muse, mutect2, varscan2
- TSPAN16 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57443606; called by muse, mutect2
- ABCA13 | c.8940G>A p.A2980= | Silent (SNP) | VAF 58/298 reads (19%) | catalogued as rs750609118, COSV71287131; called by muse, mutect2, varscan2
- ASPM | c.2034C>G p.P678= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as rs1353187923, COSV54139190; called by muse, mutect2, varscan2
- DSCAM | c.1788G>A p.P596= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs200014864; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXO11 | c.1296G>A p.A432= (on ENST00000403359 / NM_001190274.2; = p.A348= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs900098412, COSV100319189, COSV57026570; called by muse, mutect2, varscan2
- FEZF1 | c.879C>T p.C293= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs1260872793, COSV58659227; called by muse, mutect2, varscan2
- LCN12 | c.165G>A p.P55= | Silent (SNP) | VAF 46/325 reads (14%) | catalogued as rs62580418, COSV65422232; called by muse, mutect2, varscan2
- MYH15 | c.5202C>T p.S1734= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs200118280; called by muse, mutect2, varscan2
- OR6C76 | c.675C>T p.I225= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV60390109; called by muse, mutect2, varscan2
- RBL1 | c.1869G>A p.K623= | Silent (SNP) | VAF 24/279 reads (9%) | catalogued as COSV60333982; called by muse, mutect2
- RYR3 | c.5208C>T p.G1736= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs773152352, COSV66809271; called by muse, mutect2, varscan2
- ZNF283 | c.1485C>G p.T495= | Silent (SNP) | VAF 16/251 reads (6%) | catalogued as COSV61032541, COSV61033096; called by muse, mutect2
- KITLG | c.130-2197G>C | Intron (SNP) | VAF 7/49 reads (14%) | catalogued as rs918874973, COSV99933588; called by muse, mutect2, varscan2
- OR2U1P | n.719C>A | RNA (SNP) | VAF 23/173 reads (13%) | catalogued as rs1406692809; called by muse, mutect2, varscan2
